Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A7UI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A7UI-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

ICD-0-3

* Consult Report *

*Carcinoma squamous cell
non-keratinizing NOS 8072/3*

Site Cervix NOS 053.9

W 9/26/13

FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Service: [REDACTED]

Location: [REDACTED]

Accession #: [REDACTED]

Taken: [REDACTED]

Gender: F

DOB: [REDACTED]

Age: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Received: [REDACTED]

Accessioned: [REDACTED]

Reported: [REDACTED]

Physician(s): [REDACTED]

M.D.

DIAGNOSIS

UTERUS, CERVIX, BIOPSY [REDACTED]

- INVASIVE NON-KERATINIZING SQUAMOUS CELL CARCINOMA

UTERUS, ENDOCERVIX, CURETTAGE (B)

- NO EVIDENCE OF MALIGNANCY

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

[REDACTED] M.D.

***Report Electronically Reviewed and Signed Out By [REDACTED]

M.D.***

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis. [REDACTED]

History:

The patient is a [REDACTED] year old woman with abnormal Pap smear. Operative procedure: Cervical biopsy and endocervical curettage.

Materials Received:

Received are two slides labeled [REDACTED] (A recut, B), accompanied by a corresponding pathology report. The material originates from [REDACTED]

Physician Copy - [REDACTED]

Source: NCI Genomic Data Commons file fdcb5de8-16c7-430e-adae-de2112936a8e (TCGA-C5-A7UI.A07E7AF1-55EA-4EA1-A5DA-A54E17771CA9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).